Gene-level copy-number profile of tumor specimen TCGA-31-1946-01A from TCGA case TCGA-31-1946, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 30.5 years (11,146 days).
Specimen TCGA-31-1946-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.877c9240-32e0-43f3-9dfd-b4466e054bc7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-31-1946-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/136141af-9006-45de-8be1-acd85cbcba7d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 2; copy number 2: 11,508; copy number 3: 3,320; copy number 4: 33,608; copy number 5: 2,170; copy number 6: 6,869; copy number 7: 569; copy number 8: 470; copy number 9: 484; copy number 10: 45; copy number 11: 731; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-31-1946-01): tumor purity 0.7, ploidy 2.04, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,127,535–91,601,913, 1 gene (within-gene range 0–2): CCSER1.
- chr4:90,838,903–95,158,448, 29 genes (within-gene range 0–2): TMSB4XP8, AC004054.1, AC074124.1, AC110774.1, KRT19P6, AC093810.1, PMPCAP1, AC097520.2, AC097520.1, LNCPRESS2, AC112695.1, GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1, RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT, BMPR1B.
- chr16:70,579,895–70,801,160, 10 genes (within-gene range 0–2): IL34, MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,262 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:53,970,838–54,305,300, 1 gene, copy number 10 (within-gene range 8–10): ACYP2.
- chr2:54,051,334–56,181,652, 43 genes, copy number 10: HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813.
- chr2:56,173,534–56,185,870, 1 gene, copy number 10: AC007743.1.
- chr3:167,239,843–186,362,234, 335 genes, copy number 9–12 (within-gene range 7–12) (broad region; genes not listed).
- chr3:197,791,226–197,888,436, 1 gene, copy number 9 (within-gene range 7–9): LRCH3.
- chr3:197,850,400–198,222,513, 14 genes, copy number 9: AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr7:132,086,266–132,087,992, 1 gene, copy number 9: AC105443.1.
- chr8:63,384,839–72,470,972, 135 genes, copy number 9 (broad region; genes not listed).
- chr8:80,967,810–118,111,826, 524 genes, copy number 11 (broad region; genes not listed).
- chr8:139,727,725–145,066,685, 207 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
